Somatic mutation profile of tumor specimen TCGA-5X-AA5U-01A (aliquot TCGA-5X-AA5U-01A-11D-A403-09) from TCGA case TCGA-5X-AA5U, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: GX; Age at diagnosis: 61.4 years (22,438 days).
Specimen TCGA-5X-AA5U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8031507-63e2-40f1-b443-b4abf2564aae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5X-AA5U-10A (Blood Derived Normal), aliquot TCGA-5X-AA5U-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a60596f3-f3d0-42b4-b56c-4fc919c50308

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 3, Frame Shift Del 3, 3'Flank 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 25/172 reads (15%) | catalogued as rs755747010, CM062415, COSV54059230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 21/29 reads (72%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ASTN1 | c.3785G>A p.G1262E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV62493667, COSV62500386; called by muse, mutect2, varscan2
- COL17A1 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV100793124, COSV62226989; called by muse, mutect2, varscan2
- COL5A2 | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373288848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISPLD1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200705853, COSV51547514; called by muse, mutect2, varscan2
- FOXD4 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 75/230 reads (33%) | catalogued as COSV100070788; called by muse, mutect2, varscan2
- HEXIM1 | c.984_989dup p.E328_L329dup | In Frame Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs1567918156; called by mutect2, varscan2
- LAMB3 | c.1454C>G p.P485R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100620245, COSV61915749; called by muse, mutect2, varscan2
- LILRB3 | c.1606G>T p.D536Y (on ENST00000346401; = p.D524Y on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557486; called by muse, mutect2, varscan2
- NDE1 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV100706929; called by muse, mutect2, varscan2
- NFATC2 | c.743C>G p.P248R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101043920; called by muse, mutect2, varscan2
- NIPSNAP3B | c.104C>G p.T35R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV101044447; called by mutect2, varscan2
- OASL | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as rs79120918, COSV99984502; called by muse, mutect2, varscan2
- OR7A17 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs749710190, COSV100541598; called by muse, mutect2, varscan2
- PCBP1 | c.63C>G p.H21Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV57850673; called by muse, mutect2, varscan2
- PIGK | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV63062294; called by muse, mutect2, varscan2
- PRDM16 | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1415570581, COSV54598152; called by muse, mutect2, varscan2
- SERPINB12 | c.850T>C p.W284R | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99501588; called by muse, mutect2, varscan2
- SYCP2 | c.3401C>T p.T1134I | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as COSV100698148; called by muse, mutect2, varscan2
- TYK2 | c.1011+1G>T p.X337_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99314552; called by muse, mutect2, varscan2
- ZNF136 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.374); catalogued as COSV100677943; called by muse, mutect2, varscan2
- DHX32 | c.967del p.D323Mfs*16 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- NAV3 | c.3152del p.K1051Sfs*23 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CADPS | c.2148C>T p.C716= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs368353277; called by muse, mutect2, varscan2
- IRAK1 | c.1842C>T p.P614= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100888980; called by muse, mutect2, varscan2
- PCDHB5 | c.2160G>A p.P720= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs781863202, COSV99167818; called by muse, mutect2, varscan2
- PLCB1 | c.2319T>C p.Y773= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100570331; called by muse, mutect2, varscan2
- SACS | c.9774A>G p.K3258= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV101207375; called by muse, mutect2, varscan2
- SLC14A1 | c.975C>A p.G325= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100424980, COSV58931209; called by muse, mutect2, varscan2
- TPO | c.855C>A p.A285= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100220526; called by muse, mutect2, varscan2
- TRHDE | c.1648T>C p.L550= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99670217; called by muse, mutect2, varscan2
- CEP295 | chr11:93735175 del T | 3'Flank (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
